Somatic mutation profile of tumor specimen C3L-00910-02 (aliquot CPT0007860009) from CPTAC case C3L-00910, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 75.7 years (27,654 days).
Specimen C3L-00910-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d0dedec0-6c6f-4e62-adb3-5d3ac25ab30f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00910-31 (Blood Derived Normal), aliquot CPT0002930002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/904dcceb-5baf-4b09-bff7-32fddf0fbcd2

The open-access MAF lists 85 somatic variants for this specimen: 57 protein-altering or splice-affecting, 17 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 41, Silent 17, Frame Shift Del 7, Intron 6, Nonsense Mutation 4, 5'UTR 2, Splice Site 2, Splice Region 1, In Frame Del 1, Frame Shift Ins 1, 3'Flank 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- QRICH1 | c.1606C>T p.R536* | Nonsense Mutation (SNP) | VAF 38/164 reads (23%) | catalogued as rs1559930732, COSV62614640; ClinVar: pathogenic; called by muse, mutect2, varscan2
- VHL | c.258del p.V87Yfs*72 | Frame Shift Del (DEL) | VAF 78/307 reads (25%) | catalogued as rs864622545, CM951276, CM952019, COSV56546515, COSV56547374, COSV56564109; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- COL5A1 | c.4612C>A p.P1538T | Missense Mutation (SNP) | VAF 67/467 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.898); catalogued as rs1554807720; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LRRC49 | c.124A>G p.K42E | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.01); catalogued as rs1169001692; called by muse, mutect2, varscan2
- MATR3 | c.823A>G p.S275G | Missense Mutation (SNP) | VAF 35/239 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0.018); catalogued as rs375756727; called by muse, mutect2, varscan2
- MYBPC2 | c.187G>T p.V63L | Missense Mutation (SNP) | VAF 39/141 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as rs1215426262; called by muse, mutect2, varscan2
- NPY1R | c.700-1G>T p.X234_splice | Splice Site (SNP) | VAF 6/54 reads (11%) | catalogued as COSV99648729; called by muse, mutect2, varscan2
- NUMB | c.1544A>G p.N515S (on ENST00000355058; = p.N504S on NM_003744.5) | Missense Mutation (SNP) | VAF 56/246 reads (23%) | SIFT tolerated (0.37); PolyPhen benign (0.145); catalogued as rs765768042; called by muse, mutect2, varscan2
- OLIG1 | c.469G>T p.A157S | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60737719; called by muse, mutect2, varscan2
- OR11L1 | c.151C>A p.Q51K | Missense Mutation (SNP) | VAF 57/324 reads (18%) | SIFT tolerated (0.34); PolyPhen benign (0.01); catalogued as COSV63315015; called by muse, mutect2, varscan2
- OR2M5 | c.347C>T p.A116V | Missense Mutation (SNP) | VAF 180/499 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.721); catalogued as COSV100822874; called by muse, mutect2, varscan2
- PIGN | c.344G>A p.G115E | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766376855, COSV62949401; called by muse, mutect2, varscan2
- PLD5 | c.749G>T p.G250V (on ENST00000442594; = p.G188V on NM_001195811.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/170 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as COSV59148408; called by muse, mutect2, varscan2
- SF3B1 | c.1988C>T p.T663I | Missense Mutation (SNP) | VAF 98/466 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1239341681, COSV59206194; called by muse, mutect2, varscan2
- SRGAP3 | c.632G>A p.R211H | Missense Mutation (SNP) | VAF 40/150 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as rs149157821; called by muse, mutect2, varscan2
- STXBP6 | c.541G>C p.G181R | Missense Mutation (SNP) | VAF 38/124 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.913); catalogued as COSV60593990; called by muse, mutect2, varscan2
- TCF7L1 | c.1330G>A p.E444K | Missense Mutation (SNP) | VAF 79/198 reads (40%) | SIFT tolerated (0.46); PolyPhen benign (0.074); catalogued as COSV56398124; called by muse, mutect2, varscan2
- TFAP2D | c.67C>T p.R23C | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1455239820, COSV50431210, COSV99145856; called by muse, mutect2, varscan2
- UBTD1 | c.392C>T p.T131M | Missense Mutation (SNP) | VAF 23/206 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.443); catalogued as rs750347239; called by muse, mutect2, varscan2
- WWC3 | c.2818C>T p.R940* | Nonsense Mutation (SNP) | VAF 56/263 reads (21%) | catalogued as rs61111056, COSV101081477; called by muse, varscan2
- ADCY8 | c.3481C>A p.Q1161K | Missense Mutation (SNP) | VAF 33/256 reads (13%) | SIFT tolerated (0.37); PolyPhen benign (0.239); called by muse, mutect2, varscan2
- ADGRB3 | c.1261C>T p.Q421* | Nonsense Mutation (SNP) | VAF 52/195 reads (27%) | called by muse, mutect2, varscan2
- ADGRG7 | c.945A>C p.K315N | Missense Mutation (SNP) | VAF 22/127 reads (17%) | SIFT tolerated (0.65); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARHGAP31 | c.4007del p.F1336Sfs*12 | Frame Shift Del (DEL) | VAF 36/141 reads (26%) | called by mutect2, pindel, varscan2
- ARID1B | c.6109G>A p.D2037N | Missense Mutation (SNP) | VAF 67/239 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ATXN7L3B | c.113del p.H38Pfs*19 | Frame Shift Del (DEL) | VAF 53/594 reads (9%) | called by mutect2, pindel
- BBS5 | c.509_516del p.L170* | Frame Shift Del (DEL) | VAF 35/210 reads (17%) | called by mutect2, pindel, varscan2
- C11orf80 | c.570+1G>A p.X190_splice | Splice Site (SNP) | VAF 13/66 reads (20%) | called by muse, mutect2, varscan2
- C11orf80 | c.1865T>C p.L622P | Missense Mutation (SNP) | VAF 50/232 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CADPS | c.2337_2339del p.F779_E780delinsL | In Frame Del (DEL) | VAF 37/144 reads (26%) | called by mutect2, pindel, varscan2
- COL2A1 | c.3469G>T p.A1157S | Missense Mutation (SNP) | VAF 108/536 reads (20%) | SIFT tolerated (0.95); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- COMMD10 | c.462del p.K154Nfs*11 | Frame Shift Del (DEL) | VAF 60/343 reads (17%) | called by mutect2, pindel, varscan2
- CTDSPL2 | c.958G>A p.V320I | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DLG1 | c.1524dup p.G509Rfs*11 | Frame Shift Ins (INS) | VAF 74/386 reads (19%) | called by mutect2, pindel, varscan2
- DSC3 | c.2373del p.C792Afs*88 | Frame Shift Del (DEL) | VAF 113/503 reads (22%) | called by mutect2, pindel, varscan2
- GUCY2D | c.83G>C p.R28P | Missense Mutation (SNP) | VAF 43/214 reads (20%) | SIFT tolerated (0.37); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- HCRTR2 | c.821A>G p.Q274R | Missense Mutation (SNP) | VAF 83/361 reads (23%) | SIFT tolerated (0.54); PolyPhen benign (0.178); called by muse, mutect2, varscan2
- MAP1S | c.455T>G p.I152S | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- MYBPC3 | c.3502G>A p.E1168K | Missense Mutation (SNP) | VAF 29/126 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- MYO16 | c.1866G>C p.L622F | Missense Mutation (SNP) | VAF 37/151 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); called by muse, mutect2, varscan2
- NBPF12 | c.2612G>C p.G871A | Missense Mutation (SNP) | VAF 40/578 reads (7%) | SIFT tolerated (1); PolyPhen possibly damaging (0.877); called by muse, mutect2
- NCKAP5 | c.462G>C p.K154N | Missense Mutation (SNP) | VAF 36/299 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PBRM1 | c.4200del p.Q1400Hfs*81 (on ENST00000296302 / NM_001366071.2; = p.Q1348Hfs*32 on NM_018313.5) | Frame Shift Del (DEL) | VAF 91/432 reads (21%) | called by mutect2, pindel, varscan2
- PBRM1 | c.1923G>T p.L641= | Splice Region (SNP) | VAF 16/139 reads (12%) | called by muse, mutect2, varscan2
- PNMA3 | c.1031G>T p.R344M | Missense Mutation (SNP) | VAF 12/155 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); called by muse, mutect2
- POLR1E | c.1010G>T p.R337L (on ENST00000377792 / NM_001282766.1; = p.R275L on NM_022490.4) | Missense Mutation (SNP) | VAF 45/227 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PTGER3 | c.475A>C p.I159L | Missense Mutation (SNP) | VAF 28/170 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.309); called by muse, mutect2, varscan2
- RBFOX1 | c.408G>T p.M136I | Missense Mutation (SNP) | VAF 23/125 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.632); called by muse, mutect2, varscan2
- RPL4 | c.323G>T p.W108L | Missense Mutation (SNP) | VAF 16/316 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.692); called by muse, mutect2
- RSF1 | c.1826A>T p.E609V | Missense Mutation (SNP) | VAF 41/196 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.294); called by muse, mutect2, varscan2
- SCIMP | c.36G>A p.M12I | Missense Mutation (SNP) | VAF 63/325 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- SEMA4B | c.143T>G p.I48S | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.197); called by muse, mutect2
- SRCIN1 | c.723C>G p.H241Q (on ENST00000621492; = p.H207Q on NM_025248.3) | Missense Mutation (SNP) | VAF 14/387 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.237); called by muse, mutect2
- TMEM192 | c.715G>T p.G239* | Nonsense Mutation (SNP) | VAF 40/176 reads (23%) | called by muse, mutect2, varscan2
- ZFP1 | c.90G>T p.R30S | Missense Mutation (SNP) | VAF 55/260 reads (21%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.927); called by mutect2, varscan2
- ZNF268 | c.2125T>C p.S709P | Missense Mutation (SNP) | VAF 60/321 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- ZXDB | c.719C>T p.A240V | Missense Mutation (SNP) | VAF 26/122 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANKRD30A | c.3346C>T p.L1116= (on ENST00000611781; = p.L1060= on NM_052997.2) | Silent (SNP) | VAF 22/82 reads (27%) | called by muse, mutect2, varscan2
- CDH22 | c.1266C>T p.D422= | Silent (SNP) | VAF 14/57 reads (25%) | catalogued as rs982195396; called by muse, mutect2, varscan2
- CUBN | c.8859T>C p.N2953= | Silent (SNP) | VAF 92/373 reads (25%) | catalogued as rs1394285922; called by muse, mutect2, varscan2
- DAAM2 | c.1489C>T p.L497= | Silent (SNP) | VAF 38/146 reads (26%) | catalogued as rs1350876844; called by muse, mutect2, varscan2
- DOLK | c.366C>T p.A122= | Silent (SNP) | VAF 35/137 reads (26%) | called by muse, mutect2, varscan2
- F8A1 | c.1095C>G p.S365= | Silent (SNP) | VAF 54/490 reads (11%) | called by muse, mutect2, varscan2
- GAPDH | c.942T>C p.Y314= | Silent (SNP) | VAF 50/239 reads (21%) | catalogued as rs748231452; called by muse, mutect2, varscan2
- HMCN1 | c.16005C>T p.G5335= | Silent (SNP) | VAF 48/203 reads (24%) | called by muse, mutect2, varscan2
- JPH4 | c.1701C>T p.I567= | Silent (SNP) | VAF 14/54 reads (26%) | catalogued as rs528868041, COSV58110154; called by muse, mutect2, varscan2
- MAP4K1 | c.2256G>A p.A752= | Silent (SNP) | VAF 4/71 reads (6%) | catalogued as rs1420730478; called by muse, mutect2
- MUC16 | c.1017T>C p.S339= | Silent (SNP) | VAF 58/302 reads (19%) | catalogued as rs1046499551; called by muse, mutect2, varscan2
- PAX3 | c.1038C>T p.S346= | Silent (SNP) | VAF 146/680 reads (21%) | catalogued as rs758760102; called by muse, mutect2, varscan2
- PCDHAC2 | c.2136A>G p.L712= | Silent (SNP) | VAF 71/356 reads (20%) | called by muse, mutect2, varscan2
- PCDHGA8 | c.2382C>G p.S794= | Silent (SNP) | VAF 30/136 reads (22%) | catalogued as COSV99536256; called by muse, mutect2, varscan2
- SERPINB12 | c.315G>A p.R105= | Silent (SNP) | VAF 33/155 reads (21%) | called by muse, mutect2, varscan2
- TRANK1 | c.8160G>T p.V2720= | Silent (SNP) | VAF 44/138 reads (32%) | called by muse, mutect2, varscan2
- TTN | c.29796A>C p.P9932= (on ENST00000591111; = p.P9005= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 44/248 reads (18%) | called by muse, mutect2, varscan2
- AC022148.1 | n.246G>C | RNA (SNP) | VAF 37/137 reads (27%) | called by muse, mutect2, varscan2
- DDR2 | c.1504+68G>A | Intron (SNP) | VAF 60/288 reads (21%) | catalogued as rs571524258; called by muse, mutect2, varscan2
- ESRRB | c.1296+263A>G | Intron (SNP) | VAF 70/244 reads (29%) | called by muse, mutect2, varscan2
- FECH | c.1137+24T>G | Intron (SNP) | VAF 35/115 reads (30%) | called by muse, mutect2, varscan2
- HTR2C | c.-79-11610A>T | Intron (SNP) | VAF 49/220 reads (22%) | catalogued as COSV99351519; called by muse, mutect2, varscan2
- LIN28A | c.-37G>T | 5'UTR (SNP) | VAF 33/186 reads (18%) | called by muse, mutect2, varscan2
- LRRC63 | chr13:46270346 G>C | 3'Flank (SNP) | VAF 47/225 reads (21%) | called by muse, mutect2, varscan2
- RPN2 | chr20:37179254 C>T | 5'Flank (SNP) | VAF 37/130 reads (28%) | catalogued as rs1000235443; called by muse, mutect2, varscan2
- SLC39A4 | c.193-136C>T | Intron (SNP) | VAF 49/209 reads (23%) | catalogued as rs996848297, COSV52778542; called by muse, mutect2, varscan2
- SLURP1 | c.-6G>A | 5'UTR (SNP) | VAF 114/472 reads (24%) | catalogued as rs200079141, COSV99872933; called by muse, mutect2, varscan2
- SYNE2 | c.18038+792T>C | Intron (SNP) | VAF 97/408 reads (24%) | catalogued as rs910574310; called by muse, mutect2, varscan2
